Somatic mutation profile of tumor specimen MP2PRT-PAUINY-TMP1-A (aliquot MP2PRT-PAUINY-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUINY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (556 days).
Specimen MP2PRT-PAUINY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e6a2b3b-d381-42c7-a4fa-56ec0155acb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUINY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUINY-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa4a84cc-bfad-41cf-8ecb-df04acffac49

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGB | c.4463C>T p.T1488M | Missense Mutation (SNP) | VAF 152/346 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs536706312, COSV58851387; called by muse, mutect2, varscan2
- ARHGEF28 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753386846, COSV55267464; called by muse, mutect2, varscan2
- CSMD3 | c.2534G>A p.R845Q (on ENST00000297405 / NM_001363185.1; = p.R741Q on NM_052900.3) | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754786650, COSV52123877, COSV52243892; called by muse, mutect2, varscan2
- IQGAP1 | c.3462C>G p.D1154E | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNA5 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 240/568 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3R1 | c.1415_1423del p.R472_S474del (on ENST00000521381 / NM_181523.3; = p.R202_S204del on NM_181504.4) | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- SYNE1 | c.16616T>A p.I5539N (on ENST00000367255 / NM_182961.4; = p.I5468N on NM_033071.3) | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CHST1 | c.498C>T p.C166= | Silent (SNP) | VAF 159/422 reads (38%) | catalogued as rs559545692, COSV57321577; called by muse, varscan2
- KRT75 | c.75G>A p.P25= | Silent (SNP) | VAF 208/498 reads (42%) | catalogued as rs771920420; called by muse, mutect2, varscan2
